Somatic mutation profile of tumor specimen 0DQRZZ from CCDI case PBCCMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.7 years (3,917 days).
Specimen 0DQRZZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8701a6e-a129-4493-8f73-4f35a49f6f25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2decbad1-f141-4fd0-b3f6-e7f0f2418ad9

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1012015300; called by muse, mutect2, varscan2
- B3GALT1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 227/526 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59908551; called by muse, mutect2, varscan2
- LCN8 | c.286G>A p.A96T (on ENST00000612714 / NM_001345934.1; = p.A73T on NM_178469.3) | Missense Mutation (SNP) | VAF 189/427 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs754127415, COSV60209838; called by muse, mutect2, varscan2
- TMEM79 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99827658; called by muse, mutect2, varscan2
- EPC2 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 172/361 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MARF1 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 207/476 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- NWD1 | c.4633G>A p.E1545K | Missense Mutation (SNP) | VAF 170/490 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF11 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 185/383 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- POLA1 | c.2828A>C p.D943A | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSIP1 | c.1243_1244del p.K415Vfs*6 | Frame Shift Del (DEL) | VAF 186/209 reads (89%) | called by mutect2, varscan2
- COL4A2 | c.939A>G p.K313= | Silent (SNP) | VAF 277/593 reads (47%) | catalogued as COSV100847436, COSV64626269; called by muse, mutect2, varscan2
- NCKAP1L | c.3315G>A p.E1105= | Silent (SNP) | VAF 168/565 reads (30%) | catalogued as rs746154508; called by muse, mutect2, varscan2
- ZNF787 | c.261G>A p.T87= | Silent (SNP) | VAF 137/307 reads (45%) | catalogued as rs750101073, COSV99555792; called by muse, mutect2, varscan2
- ATP11A | c.2668-98G>T | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as COSV52108217; called by muse, varscan2
- RHBDD2 | chr7:75879014 C>T | 5'Flank (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
